Somatic mutation profile of tumor specimen TCGA-CC-A9FU-01A (aliquot TCGA-CC-A9FU-01A-11D-A36X-10) from TCGA case TCGA-CC-A9FU, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 52.9 years (19,326 days).
Specimen TCGA-CC-A9FU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 19e9f992-8218-4e8a-bf8a-9c2d00cdc02f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CC-A9FU-10A (Blood Derived Normal), aliquot TCGA-CC-A9FU-10A-01D-A370-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/65a75579-73e5-413d-b199-19be1eef4323

The open-access MAF lists 49 somatic variants for this specimen: 41 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 7, Nonsense Mutation 2, Frame Shift Ins 2, Splice Region 2, Splice Site 2, Frame Shift Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAM23 | c.1681C>T p.R561W | Missense Mutation (SNP) | VAF 45/107 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1436495199, COSV100008749; called by muse, mutect2, varscan2
- AGMO | c.895T>A p.F299I | Missense Mutation (SNP) | VAF 43/111 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.186); catalogued as COSV100694690; called by muse, mutect2, varscan2
- AXIN1 | c.1020-1G>T p.X340_splice | Splice Site (SNP) | VAF 43/52 reads (83%) | catalogued as COSV51988941, COSV51990369; called by muse, mutect2, varscan2
- CCDC39 | c.2669G>A p.R890K | Missense Mutation (SNP) | VAF 40/87 reads (46%) | SIFT tolerated (0.24); PolyPhen benign (0.01); catalogued as rs1411654281, COSV56479641; called by muse, mutect2, varscan2
- CYTIP | c.62G>A p.G21E | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.36); catalogued as rs773448120, COSV99938924; called by muse, mutect2, varscan2
- DEPDC1 | c.1610A>T p.N537I | Missense Mutation (SNP) | VAF 61/140 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.024); catalogued as COSV100920469; called by muse, mutect2, varscan2
- DMRTA2 | c.926C>A p.S309* | Nonsense Mutation (SNP) | VAF 13/32 reads (41%) | catalogued as COSV101288905; called by muse, mutect2, varscan2
- DNAH10 | c.6385G>A p.V2129I (on ENST00000409039; = p.V2068I on NM_207437.3) | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.345); catalogued as rs557513283, COSV68992263; called by muse, mutect2, varscan2
- ELOA | c.1270G>A p.D424N | Missense Mutation (SNP) | VAF 83/94 reads (88%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.767); catalogued as COSV101403843; called by muse, mutect2, varscan2
- EOGT | c.1312G>A p.D438N (on ENST00000383701 / NM_001278689.2; = p.D354N on NM_173654.3) | Missense Mutation (SNP) | VAF 67/106 reads (63%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); catalogued as COSV99809155; called by muse, mutect2, varscan2
- ESS2 | c.956G>T p.G319V | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99351213; called by muse, mutect2, varscan2
- FAM209B | c.275G>T p.G92V | Missense Mutation (SNP) | VAF 148/233 reads (64%) | SIFT deleterious (0); PolyPhen benign (0.118); catalogued as COSV100991023; called by muse, mutect2, varscan2
- FLT1 | c.1997A>T p.N666I | Missense Mutation (SNP) | VAF 57/65 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV99166536; called by muse, mutect2, varscan2
- GABRG1 | c.1257T>G p.F419L | Missense Mutation (SNP) | VAF 8/196 reads (4%) | SIFT tolerated (0.37); PolyPhen benign (0.15); catalogued as COSV54960521, COSV99778711; called by muse, mutect2
- IMPG1 | c.1278G>T p.E426D | Missense Mutation (SNP) | VAF 60/135 reads (44%) | SIFT tolerated (0.43); PolyPhen benign (0.104); catalogued as COSV100886651; called by muse, mutect2, varscan2
- ITPR2 | c.5546G>T p.R1849L | Missense Mutation (SNP) | VAF 51/97 reads (53%) | SIFT tolerated (0.3); PolyPhen benign (0.018); catalogued as COSV101190155, COSV67272085; called by muse, mutect2, varscan2
- LCN15 | c.487C>A p.P163T | Missense Mutation (SNP) | VAF 70/168 reads (42%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as COSV100293618; called by muse, mutect2, varscan2
- LRIG3 | c.3340T>A p.S1114T | Missense Mutation (SNP) | VAF 34/52 reads (65%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.001); catalogued as COSV100292827; called by muse, mutect2, varscan2
- MAP2K3 | c.178G>C p.E60Q (on ENST00000342679 / NM_145109.3; = p.E31Q on NM_002756.4) | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT tolerated (0.43); PolyPhen benign (0.055); catalogued as COSV100384464; called by muse, mutect2
- MEOX1 | c.302C>T p.A101V | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.164); catalogued as COSV100233796, COSV59356644; called by muse, mutect2, varscan2
- MYF5 | c.731G>C p.G244A | Missense Mutation (SNP) | VAF 32/54 reads (59%) | SIFT tolerated (0.46); PolyPhen benign (0.19); catalogued as COSV99953394; called by muse, mutect2, varscan2
- OR10A3 | c.582A>T p.L194F | Missense Mutation (SNP) | VAF 45/167 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.036); catalogued as COSV100660328, COSV62459396; called by muse, mutect2, varscan2
- PDZK1IP1 | c.286G>T p.E96* | Nonsense Mutation (SNP) | VAF 22/59 reads (37%) | catalogued as COSV99595696; called by muse, mutect2, varscan2
- PIGS | c.916C>T p.P306S | Missense Mutation (SNP) | VAF 45/69 reads (65%) | SIFT deleterious (0); PolyPhen benign (0.265); catalogued as COSV99257256; called by muse, mutect2, varscan2
- RBM45 | c.580A>T p.N194Y | Missense Mutation (SNP) | VAF 59/165 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as COSV99618009; called by muse, mutect2, varscan2
- RTRAF | c.76A>G p.R26G | Missense Mutation (SNP) | VAF 156/261 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1442823459, COSV99911028; called by muse, mutect2, varscan2
- SASH1 | c.1234G>C p.D412H | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100821435; called by muse, mutect2, varscan2
- SETD2 | c.5263C>G p.L1755V | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV57443831, COSV57447953, COSV57457819; called by muse, mutect2, varscan2
- SFXN4 | c.540A>T p.V180= | Splice Region (SNP) | VAF 24/57 reads (42%) | catalogued as COSV100341235; called by muse, mutect2, varscan2
- SOX13 | c.1762G>A p.D588N | Missense Mutation (SNP) | VAF 63/196 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.031); catalogued as COSV65827815, COSV99690049; called by muse, mutect2, varscan2
- SOX5 | c.1001G>A p.G334D | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.307); catalogued as COSV100508079; called by muse, mutect2, varscan2
- THOC2 | c.4518A>G p.T1506= | Splice Region (SNP) | VAF 65/78 reads (83%) | catalogued as COSV99834135; called by muse, varscan2
- TRPS1 | c.3161C>A p.S1054Y (on ENST00000220888 / NM_001330599.2; = p.S1067Y on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 123/135 reads (91%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.804); catalogued as rs78385846, COSV55226849, COSV99634193; called by muse, mutect2, varscan2
- TTN | c.59045C>T p.T19682I (on ENST00000591111; = p.T12258I on NM_003319.4) | Missense Mutation (SNP) | VAF 59/125 reads (47%) | PolyPhen possibly damaging (0.651); catalogued as COSV100628990; called by muse, mutect2, varscan2
- TTYH1 | c.251C>G p.S84W | Missense Mutation (SNP) | VAF 56/65 reads (86%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.555); catalogued as COSV100002411, COSV56613913; called by muse, mutect2, varscan2
- UBR5 | c.1608G>C p.L536F | Missense Mutation (SNP) | VAF 28/129 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); catalogued as COSV55284726, COSV99642285; called by muse, mutect2, varscan2
- ZNF703 | c.260G>A p.S87N | Missense Mutation (SNP) | VAF 20/28 reads (71%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV100521800; called by muse, mutect2, varscan2
- BRINP3 | c.1221_1225del p.F407Lfs*4 | Frame Shift Del (DEL) | VAF 62/284 reads (22%) | called by mutect2, pindel, varscan2
- BRSK1 | c.1347+2_1347+4dup p.X449_splice | Splice Site (INS) | VAF 16/79 reads (20%) | called by mutect2, pindel, varscan2
- LPA | c.5913dup p.K1972* | Frame Shift Ins (INS) | VAF 14/47 reads (30%) | called by mutect2, pindel, varscan2
- REXO1 | c.872_876dup p.A293Mfs*202 | Frame Shift Ins (INS) | VAF 44/56 reads (79%) | called by mutect2, varscan2
- CSMD3 | c.2391T>A p.P797= (on ENST00000297405 / NM_001363185.1; = p.P693= on NM_052900.3) | Silent (SNP) | VAF 103/107 reads (96%) | catalogued as COSV99846898; called by muse, mutect2, varscan2
- LONRF2 | c.1548A>G p.E516= | Silent (SNP) | VAF 52/122 reads (43%) | catalogued as rs1559177170, COSV101111055; called by muse, varscan2
- OR4A16 | c.915T>C p.S305= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as rs762129860, COSV59044670; called by muse, mutect2, varscan2
- PLEKHA6 | c.2658C>T p.G886= | Silent (SNP) | VAF 41/124 reads (33%) | catalogued as rs1475287376, COSV99692723; called by muse, mutect2, varscan2
- PNMA8B | c.930C>T p.D310= | Silent (SNP) | VAF 14/149 reads (9%) | catalogued as COSV100885527; called by muse, mutect2, varscan2
- SVEP1 | c.7425T>C p.N2475= | Silent (SNP) | VAF 52/65 reads (80%) | catalogued as COSV99929749; called by muse, mutect2, varscan2
- ZSCAN29 | c.135G>T p.R45= | Silent (SNP) | VAF 20/63 reads (32%) | catalogued as COSV53018621; called by muse, mutect2, varscan2
- DPP6 | c.627+21081T>A | Intron (SNP) | VAF 45/92 reads (49%) | catalogued as COSV100127989; called by muse, mutect2, varscan2
